Gene-level copy-number profile of tumor specimen TCGA-WA-A7GZ-01A from TCGA case TCGA-WA-A7GZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; Tumor grade: G2; Age at diagnosis: 58.1 years (21,207 days).
Specimen TCGA-WA-A7GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8d359280-c54f-4708-9aff-16c3396bf261.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WA-A7GZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12a142ed-7b45-45a4-8556-a870f6deba3c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 176; copy number 2: 12,317; copy number 3: 13,371; copy number 4: 28,602; copy number 5: 1,159; copy number 6: 2,703; copy number 7: 809; copy number 8: 329; copy number 9: 268; copy number 16: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WA-A7GZ-01A-11D-A34I-01): tumor purity 0.43, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,911,096–133,119,052, 3 genes: AC016909.1, NCKAP5-AS1, AC011755.1.
- chr2:186,486,253–186,765,959, 5 genes (within-gene range 0–2): ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B.
- chr3:78,758,974–78,938,292, 2 genes: AC055731.1, RN7SL751P.
- chr6:101,430,411–101,454,245, 2 genes: ACTG1P18, AP002528.1.
- chr7:122,073,549–122,234,903, 5 genes: AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1.
- chr8:150,584–477,967, 15 genes (within-gene range 0–2): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1.
- chr8:2,493,876–2,877,916, 8 genes: AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1.
- chr8:2,935,353–4,994,972, 4 genes (within-gene range 0–2): CSMD1, AC026991.1, AC026991.2, RNA5SP251.
- chr10:34,109,560–34,815,325, 1 gene (within-gene range 0–2): PARD3.
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 303 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:31,497,423–43,674,591, 235 genes, copy number 9–16 (broad region; genes not listed).
- chr22:20,058,030–21,081,018, 68 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
